Gene-level copy-number profile of tumor specimen TCGA-37-4135-01A from TCGA case TCGA-37-4135, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 68.6 years (25,041 days).
Specimen TCGA-37-4135-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.af476982-2b11-4415-91ac-9f197ff3c775.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-37-4135-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2 (2 files); AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e9d62a61-b991-49e3-ac8c-47d9f4708abe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,678; copy number 2: 24,908; copy number 3: 16,029; copy number 4: 9,145; copy number 5: 4,488; copy number 6: 662; copy number 7: 504; copy number 8: 358; copy number 9: 529; copy number 10: 127; copy number 11: 110; copy number 12: 73; copy number 13: 63; copy number 15: 77; copy number 16: 20; copy number 17: 1; copy number 28: 42.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-37-4135-01A-01D-1969-01): tumor purity 0.91, ploidy 2.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,054 genes in 48 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–192,957,713, 1,392 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr1:193,457,422–248,919,946, 1,198 genes, copy number 5 (broad region; genes not listed).
- chr2:5,602,505–6,918,734, 21 genes, copy number 5 (within-gene range 2–5): LINC01248, AC108025.1, SOX11, AC010729.2, AC010729.1, LINC01810, SILC1, MIR7158, AC017053.1, LINC01247, LINC01824, PIK3CDP1, MIR7515HG, AC097517.1, MIR7515, LINC00487, NRIR, CMPK2, RSAD2, AC017076.1, GRASLND.
- chr2:13,000,953–14,650,814, 8 genes, copy number 5: AC093912.1, AC073062.1, LINC00276, AC016730.1, RNU6-1288P, Metazoa_SRP, AC011897.1, LRATD1.
- chr2:94,725,674–96,642,787, 87 genes, copy number 10 (within-gene range 3–10) (broad region; genes not listed).
- chr3:76,434,018–77,571,881, 4 genes, copy number 5: CAP1P1, RNU6-386P, VDAC1P7, AC133040.1.
- chr3:87,051,192–88,601,402, 21 genes, copy number 8–17: PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5.
- chr3:108,822,770–111,665,750, 32 genes, copy number 5–7 (within-gene range 3–7): TRAT1, GUCA1C, MORC1, U3, MORC1-AS1, C3orf85, AC063923.2, LINC00488, RNU6-1236P, AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15, MIR4445, AC078980.1, DIMT1P1, NFYBP1, AC078918.1, AC117430.1, RNU6ATAC15P, RPSAP29, Y_RNA, NECTIN3-AS1, NECTIN3, CD96, AC092916.1, ATP6V0CP2.
- chr3:117,719,859–167,924,011, 870 genes, copy number 5–12 (within-gene range 4–12) (broad region; genes not listed).
- chr3:167,888,414–198,222,513, 603 genes, copy number 5–9 (broad region; genes not listed).
- chr4:51,978,079–60,038,586, 139 genes, copy number 6–12 (broad region; genes not listed).
- chr6:148,001,716–150,025,532, 57 genes, copy number 5–6: AL445123.2, AL445123.1, AL359382.1, AL359382.2, AL513164.1, SASH1, RNU6-1222P, CYP51A1P3, SNRPEP6, RPSAP40, UST, UST-AS1, UST-AS2, AL603766.1, AL031056.1, TAB2, TAB2-AS1, AL031056.2, RN7SL234P, FABP12P1, SUMO4, ZC3H12D, AL031133.1, PPIL4, RNU7-3P, AL078581.3, GINM1, AL078581.4, AL078581.2, RPS18P9, AL078581.1, KATNA1, Y_RNA, LATS1, AL358852.1, NUP43, PCMT1, BTBD10P2, AL355312.2, AL355312.4, AL355312.5, LRP11, AL355312.3, RAET1E-AS1, CCT7P1, RAET1E, RAET1E-AS1, AL355312.1, RAET1G, AL583835.2, ULBP2, AL583835.1, ULBP1, AL355497.1, BTF3P10, RAET1K, RAET1L.
- chr6:151,364,115–170,738,536, 330 genes, copy number 7 (broad region; genes not listed).
- chr8:12,393,209–14,023,422, 43 genes, copy number 5: DEFB109A, AC087203.3, FAM90A25P, ALG1L12P, FAM86B2, ENPP7P6, AC068587.4, AC130352.1, RPS3AP34, AC068587.2, AC068587.8, AC068587.6, RPS3AP35, AC068587.3, AC068587.7, AC068587.5, AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022832.2, AC022880.2, AC022880.1, AC022690.2, AC022690.1, AC023538.1.
- chr8:16,598,758–16,915,044, 3 genes, copy number 7 (within-gene range 4–7): AC011586.2, AC011586.1, RN7SL474P.
- chr8:84,948,585–85,951,083, 31 genes, copy number 8: ACTBP6, JCHAINP1, AC091175.1, LRRCC1, AC011773.4, E2F5, AC011773.1, RBIS, CA13, AC011773.3, AC011773.2, CA1, CA3, CA3-AS1, CA2, AC084734.1, AC093331.1, REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849.
- chr11:48,579,436–50,422,316, 61 genes, copy number 5–9 (broad region; genes not listed).
- chr11:68,903,863–70,436,584, 49 genes, copy number 16–28: IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,706,068, 6 genes, copy number 28: AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1.
- chr11:72,410,716–73,397,474, 34 genes, copy number 10: AP003785.1, ART2BP, ART2P, AP005019.2, AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1, ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2, FCHSD2, RNU6-672P, AP002381.1, AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4.
- chr11:76,759,916–79,441,030, 57 genes, copy number 12: AP003119.1, TSKU, AP003119.2, AP003119.3, ACER3, AP002498.1, B3GNT6, CAPN5, OMP, MYO7A, GDPD4, TOMM20P1, PAK1, AP003680.1, CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4, AP002768.1, AP002957.1, AP001547.1, MIR708, MIR5579.
- chr11:81,175,201–81,556,425, 3 genes, copy number 15 (within-gene range 4–15): AP003464.1, MTND4LP18, MTND6P25.
- chr11:81,842,435–81,987,813, 3 genes, copy number 15: AP002802.2, MIR4300, AP002802.1.
- chr11:89,177,875–92,896,470, 85 genes, copy number 5–13 (within-gene range 1–13) (broad region; genes not listed).
- chr11:97,657,464–111,730,855, 190 genes, copy number 8–15 (broad region; genes not listed).
- chr12:23,529,504–42,144,874, 270 genes, copy number 5–9 (broad region; genes not listed).
- chr12:43,560,784–44,389,762, 10 genes, copy number 6 (within-gene range 4–6): AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP.
- chr15:19,878,555–23,687,305, 174 genes, copy number 9 (broad region; genes not listed).
- chr15:96,756,987–96,842,384, 4 genes, copy number 6: FAM149B1P1, SPATA8-AS1, SPATA8, RN7SKP181.
- chr18:47,390–712,662, 23 genes, copy number 6: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2.
- chr18:735,746–739,662, 3 genes, copy number 6: AP001020.3, AP001020.1, AP001020.2.
- chr18:2,847,006–5,385,330, 53 genes, copy number 6: EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1, PPIAP14, LINC01892, BOD1P2, AKAIN1, AP005380.1, AP001496.4, AP001496.2, LINC00526, LINC00667, AP001496.3, ZBTB14, AP001496.1, AP005671.1.
- chr18:29,048,620–29,361,963, 3 genes, copy number 6: RNU6-408P, AC105245.1, AC074237.1.
- chr18:33,851,100–36,067,576, 38 genes, copy number 5 (within-gene range 3–5): NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A.
- chr18:37,234,119–41,819,421, 31 genes, copy number 5–6: AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40, AC108452.1, AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1, AC079052.1, KC6, NPM1P1, AC011225.1.
- chr18:43,499,173–48,410,752, 77 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr19:12,643,275–16,628,204, 225 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr20:43,652,523–64,313,132, 546 genes, copy number 5 (broad region; genes not listed).
- chr21:15,102,313–15,627,342, 7 genes, copy number 7 (within-gene range 4–7): AF222684.1, AF222685.1, AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1.
- chr22:20,299,760–23,322,927, 251 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,678. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
